Somatic mutation profile of tumor specimen TCGA-MF-A522-01A (aliquot TCGA-MF-A522-01A-11D-A25L-08) from TCGA case TCGA-MF-A522, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.9 years (20,051 days).
Specimen TCGA-MF-A522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4562460b-880a-44fe-a0e5-9e8f763b78b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MF-A522-10A (Blood Derived Normal), aliquot TCGA-MF-A522-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b41ed97-1a6f-43ec-9c6b-649d6b0116ab

The open-access MAF lists 623 somatic variants for this specimen: 433 protein-altering or splice-affecting, 174 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 174, Nonsense Mutation 26, Splice Site 7, Frame Shift Del 6, Intron 6, Splice Region 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYRK1A | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | catalogued as rs780441716, COSV58295398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1561G>C p.E521Q (on ENST00000297504 / NM_001282291.2; = p.E504Q on NM_007188.5) | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99874497; called by muse, mutect2, varscan2
- ABCF3 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 40/547 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV53053385, COSV99491452; called by muse, mutect2
- ABCG8 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs754172713, COSV99699867; called by muse, mutect2, varscan2
- ACAT2 | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV100364906, COSV58457385; called by muse, mutect2, varscan2
- ACLY | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61249454; called by muse, mutect2, varscan2
- ACOXL | c.5G>T p.R2I | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV100490279; called by muse, mutect2, varscan2
- ACOXL | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100490283; called by muse, mutect2, varscan2
- ADAM22 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV55971549, COSV99717133; called by muse, mutect2, varscan2
- ADAM23 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV100007792; called by muse, mutect2, varscan2
- ADAMTS6 | c.2910+1G>A p.X970_splice | Splice Site (SNP) | VAF 43/214 reads (20%) | catalogued as COSV100068419, COSV58683939; called by muse, mutect2, varscan2
- AHNAK2 | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV100317739; called by muse, mutect2
- AKAP3 | c.1210T>A p.Y404N | Missense Mutation (SNP) | VAF 51/1305 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV99962211; called by muse, mutect2
- AL121899.2 | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 123/340 reads (36%) | catalogued as COSV101198485; called by muse, mutect2, varscan2
- ALG1L | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs770698301, COSV100444818; called by muse, mutect2, varscan2
- ALOX5 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as COSV100980079; called by muse, varscan2
- ALOX5 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV65552533, COSV65553112; called by muse, varscan2
- AMELX | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 114/228 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100498284; called by muse, mutect2, varscan2
- APIP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99551648; called by muse, mutect2, varscan2
- APLF | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100376743, COSV58142399; called by muse, mutect2, varscan2
- APOB | c.10906G>A p.E3636K | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV99265923; called by muse, mutect2, varscan2
- ARHGAP44 | c.376T>A p.L126M | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as COSV99310855; called by muse, mutect2, varscan2
- ARHGEF26 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as rs1472983356, COSV100726575; called by muse, mutect2
- ARID4A | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100794314; called by muse, mutect2, varscan2
- ARMC6 | c.316C>T p.R106C (on ENST00000392336; = p.R81C on NM_033415.4) | Missense Mutation (SNP) | VAF 56/852 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs771359865, COSV99523051; called by muse, mutect2
- ASCC3 | c.5653G>C p.D1885H | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100976557; called by muse, varscan2
- ASCC3 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV100225835; called by muse, mutect2, varscan2
- ATG16L1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 200/528 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); catalogued as COSV100731323; called by muse, mutect2, varscan2
- ATM | c.1775G>A p.S592N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs776911505, COSV99589874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 193/1772 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as COSV100755808; called by muse, mutect2, varscan2
- ATP10D | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 97/377 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV99905676; called by muse, mutect2, varscan2
- ATP11B | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100017817; called by muse, mutect2
- ATP11B | c.1927A>G p.I643V | Missense Mutation (SNP) | VAF 72/776 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100017819; called by muse, mutect2
- ATP2A1 | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100837307; called by muse, mutect2, varscan2
- ATP6V0A2 | c.828A>G p.V276= | Splice Region (SNP) | VAF 25/194 reads (13%) | catalogued as COSV100377032; called by muse, mutect2, varscan2
- AUH | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs529693736, COSV57861958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B9D2 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99699157; called by muse, mutect2, varscan2
- BAIAP2 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100348223; called by muse, mutect2, varscan2
- BAIAP3 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100181539; called by muse, mutect2, varscan2
- BCL9 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 20/365 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.92); catalogued as rs782218422, COSV52351632; called by muse, mutect2
- BLNK | c.1334A>C p.D445A | Missense Mutation (SNP) | VAF 138/392 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99813952; called by muse, mutect2, varscan2
- BLVRA | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99646010; called by muse, mutect2, varscan2
- BLVRA | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99646011; called by muse, mutect2, varscan2
- BLZF1 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 30/497 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100250651; called by muse, mutect2
- BMPR1A | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs759014147, COSV100923560, COSV64407967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.9656C>T p.S3219F | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.955); catalogued as rs1419761928, COSV101200902; called by muse, mutect2, varscan2
- BRD7 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV99576077; called by muse, mutect2, varscan2
- BRINP3 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100818893, COSV66517294; called by muse, mutect2
- BUD31 | c.62C>G p.T21R | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99769113; called by muse, mutect2, varscan2
- C1orf174 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376225997; called by muse, mutect2, varscan2
- C1orf35 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 170/218 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99683234; called by muse, mutect2, varscan2
- C2CD5 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV100448801; called by muse, mutect2, varscan2
- C8B | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 169/444 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100980791, COSV64776445; called by muse, mutect2, varscan2
- C9orf153 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV100188667; called by muse, mutect2, varscan2
- CACNA1C | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100219351; called by muse, mutect2
- CACNA1C | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100219353; called by muse, mutect2
- CACNA1C | c.5143C>G p.R1715G | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV100219354; called by muse, mutect2, varscan2
- CACNA1E | c.3415A>T p.T1139S | Missense Mutation (SNP) | VAF 83/113 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100702970; called by muse, mutect2, varscan2
- CACNA1H | c.6571T>A p.C2191S | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99326759; called by muse, mutect2, varscan2
- CAD | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 163/790 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99255149; called by muse, mutect2, varscan2
- CAMTA2 | c.1941G>C p.Q647H | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61832955; called by muse, mutect2, varscan2
- CAPN9 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 94/811 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.08); catalogued as rs984018565, COSV55234990, COSV99680522; called by muse, mutect2, varscan2
- CASS4 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 120/237 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100824738; called by muse, mutect2, varscan2
- CBLIF | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 126/188 reads (67%) | catalogued as COSV99950973; called by muse, mutect2, varscan2
- CC2D2B | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as rs1215015186, COSV100729452; called by muse, mutect2, varscan2
- CCDC50 | c.1039C>T p.Q347* (on ENST00000392455 / NM_178335.3; = p.Q171* on NM_174908.4) | Nonsense Mutation (SNP) | VAF 42/327 reads (13%) | catalogued as COSV101165298; called by muse, mutect2, varscan2
- CCKBR | c.1342T>C p.*448Rext*13 | Nonstop Mutation (SNP) | VAF 81/107 reads (76%) | catalogued as COSV100582968; called by muse, mutect2, varscan2
- CCN6 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100037061; called by muse, mutect2, varscan2
- CCNF | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53538782; called by muse, mutect2, varscan2
- CD2 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV101040395, COSV101040419; called by muse, mutect2, varscan2
- CD244 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.191); catalogued as COSV100458599; called by muse, mutect2, varscan2
- CD247 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 488/587 reads (83%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV100758385, COSV100758394; called by muse, mutect2, varscan2
- CD5L | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 125/162 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV100941063; called by muse, mutect2, varscan2
- CD80 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV99956177, COSV99956292; called by muse, mutect2, varscan2
- CD86 | c.547G>A p.D183N (on ENST00000330540 / NM_175862.5; = p.D177N on NM_006889.4) | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as rs867896306, COSV52605354, COSV52608274; called by muse, mutect2
- CDC42BPA | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 88/623 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778676544, COSV100505489; called by muse, mutect2, varscan2
- CDC73 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 541/658 reads (82%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as COSV100813889; called by muse, mutect2, varscan2
- CDCA5 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414516250, COSV99297860; called by muse, mutect2, varscan2
- CDH7 | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100542505; called by muse, mutect2
- CDKN2A | c.332del p.G111Afs*35 | Frame Shift Del (DEL) | VAF 73/126 reads (58%) | catalogued as COSV58702846, COSV58728739; called by mutect2, pindel, varscan2
- CDX2 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV101122687; called by muse, mutect2, varscan2
- CFAP53 | c.1419T>A p.F473L | Missense Mutation (SNP) | VAF 255/495 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV101274993; called by muse, mutect2, varscan2
- CFTR | c.3912G>T p.L1304F | Missense Mutation (SNP) | VAF 102/132 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136683; called by muse, mutect2, varscan2
- CHAF1B | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100023591; called by muse, mutect2, varscan2
- CHAT | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.499); catalogued as COSV100340243; called by muse, mutect2, varscan2
- CHL1 | c.2590G>C p.E864Q (on ENST00000397491 / NM_001253387.1; = p.E880Q on NM_006614.4) | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV99851398; called by muse, mutect2, varscan2
- CHRDL1 | c.805C>A p.P269T (on ENST00000372045; = p.P275T on NM_145234.4) | Missense Mutation (SNP) | VAF 204/262 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99488236; called by muse, mutect2, varscan2
- CHST10 | c.809G>C p.C270S | Missense Mutation (SNP) | VAF 247/456 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753676063, COSV99959024; called by muse, mutect2, varscan2
- CLUL1 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100620991; called by muse, mutect2, varscan2
- CNTN3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs755419841, COSV99724682; called by muse, mutect2, varscan2
- CNTN6 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.46); catalogued as rs1001304617, COSV100610820; called by muse, mutect2, varscan2
- CNTNAP1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs751281750, COSV99226505; called by muse, mutect2, varscan2
- COL28A1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258651; called by muse, mutect2
- COL5A1 | c.5155G>A p.E1719K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs776640704, COSV100880036, COSV100880084; called by muse, mutect2, varscan2
- CR1L | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 342/437 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs1339193759, COSV99687520; called by muse, mutect2, varscan2
- CRACR2A | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 62/996 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV99365078; called by muse, mutect2
- CSMD3 | c.8633C>A p.P2878H (on ENST00000297405 / NM_001363185.1; = p.P2709H on NM_052900.3) | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836100; called by muse, mutect2, varscan2
- CST9L | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 166/541 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs367975014, COSV100980871; called by muse, mutect2, varscan2
- CTC1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 195/366 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV100236486; called by muse, mutect2, varscan2
- CYP2A6 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1490857650, COSV99991866; called by muse, mutect2, varscan2
- DCAF13 | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV99885394; called by muse, mutect2, varscan2
- DCC | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500489, COSV59100849; called by muse, mutect2, varscan2
- DHX57 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99769583; called by muse, mutect2, varscan2
- DIS3L2 | c.2593C>T p.H865Y | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as rs1559221737, COSV99806420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLC1 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 352/464 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs751041425, COSV99363456; called by muse, mutect2, varscan2
- DLG1 | c.857A>C p.D286A | Missense Mutation (SNP) | VAF 21/596 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV100015439; called by muse, mutect2
- DLG1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 21/594 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1178053626, COSV100014913; called by muse, mutect2
- DNA2 | c.1775G>C p.R592P | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622610; called by muse, mutect2, varscan2
- DNAH8 | c.6025G>C p.E2009Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV100545681; called by muse, mutect2, varscan2
- DNAH9 | c.4714C>A p.L1572M | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99306142; called by muse, mutect2, varscan2
- DNAJC10 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51137314, COSV99899325; called by muse, mutect2, varscan2
- DSEL | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.22); catalogued as COSV100025707; called by muse, mutect2, varscan2
- ECD | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100881440; called by muse, mutect2, varscan2
- EDC3 | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 125/215 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100165970; called by muse, mutect2, varscan2
- EIF1AX | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV101096055; called by muse, mutect2, varscan2
- EIF4A2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 135/1164 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV60623750; called by muse, mutect2, varscan2
- EIF4G3 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV99944471; called by muse, mutect2, varscan2
- EIF4G3 | c.656-1G>C p.X219_splice | Splice Site (SNP) | VAF 52/246 reads (21%) | catalogued as COSV99944472; called by muse, mutect2, varscan2
- EML5 | c.4666A>G p.T1556A (on ENST00000380664; = p.T1564A on NM_183387.3) | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100715710; called by muse, mutect2, varscan2
- EPB41 | c.1310T>C p.V437A (on ENST00000343067 / NM_001166005.2; = p.V228A on NM_004437.4) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100548730; called by muse, mutect2, varscan2
- EPB41L5 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1356047922, COSV99758780; called by muse, mutect2, varscan2
- ERMARD | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200063598, COSV100824578; called by muse, mutect2, varscan2
- ESPNL | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as rs1345255870, COSV100547824; called by muse, mutect2, varscan2
- ETV4 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as rs780292322, COSV100081726; called by muse, mutect2, varscan2
- ETV7 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 49/214 reads (23%) | catalogued as COSV100339215; called by muse, mutect2, varscan2
- EVC2 | c.2359C>G p.R787G | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100186115; called by muse, mutect2, varscan2
- EXOC1 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.248); catalogued as COSV100637891; called by muse, mutect2, varscan2
- EXOC4 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV99554230; called by muse, mutect2, varscan2
- F13A1 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV53565322; called by muse, mutect2
- FAM133A | c.452C>A p.S151* | Nonsense Mutation (SNP) | VAF 34/40 reads (85%) | catalogued as COSV100220419; called by muse, mutect2, varscan2
- FAM135B | c.3439G>T p.G1147C | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424442; called by muse, mutect2, varscan2
- FAM135B | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 146/311 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV50532393; called by muse, mutect2, varscan2
- FAM13C | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99513980; called by muse, mutect2, varscan2
- FAM204A | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV100977442; called by muse, mutect2, varscan2
- FAM217B | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 87/453 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.026); catalogued as COSV100674458; called by muse, mutect2, varscan2
- FANCG | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 394/486 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1315754695, COSV100734224; called by muse, mutect2, varscan2
- FBN1 | c.7856G>T p.G2619V | Missense Mutation (SNP) | VAF 173/295 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100355302; called by muse, mutect2, varscan2
- FBXO11 | c.1235G>A p.G412E (on ENST00000403359 / NM_001190274.2; = p.G328E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100319549; called by muse, mutect2, varscan2
- FBXW7 | c.1873A>G p.S625G (on ENST00000281708 / NM_001349798.2; = p.S545G on NM_018315.5) | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); catalogued as COSV99657445; called by muse, mutect2, varscan2
- FERD3L | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 131/211 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99284953; called by muse, mutect2, varscan2
- FERMT1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV99451647; called by muse, mutect2, varscan2
- FHDC1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99471340; called by muse, mutect2, varscan2
- FKBP9 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99639848; called by muse, mutect2, varscan2
- FLG | c.9730C>A p.Q3244K | Missense Mutation (SNP) | VAF 188/2382 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV100911629; called by muse, mutect2
- FMN2 | c.4872A>C p.Q1624H | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV60422561, COSV60449037; called by muse, mutect2
- FOXG1 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100486863; called by muse, mutect2, varscan2
- FRAS1 | c.2596A>T p.T866S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV53632788; called by muse, mutect2, varscan2
- FRY | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV66569478, COSV66576198; called by muse, mutect2, varscan2
- FSIP2 | c.19165G>A p.V6389I | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as COSV100555346; called by muse, mutect2, varscan2
- FUT4 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs763921366, COSV100708098; called by muse, varscan2
- GABRD | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 101/175 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs901937998, COSV101059546, COSV101059558; called by muse, mutect2, varscan2
- GCM1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452399; called by muse, mutect2, varscan2
- GCSAM | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 97/708 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV100453292; called by muse, mutect2, varscan2
- GFI1 | c.1145A>T p.N382I | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM031689, COSV99647547; called by muse, mutect2, varscan2
- GGTLC1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 322/605 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53846236; called by muse, mutect2, varscan2
- GJD2 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99290776; called by muse, mutect2, varscan2
- GLCCI1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99780456, COSV99780711; called by muse, mutect2
- GLCCI1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99780457; called by muse, mutect2
- GLP2R | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as COSV99302076; called by muse, mutect2
- GMEB2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs752805008, COSV56607678; called by muse, mutect2, varscan2
- GOLGB1 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 68/1066 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100510740, COSV100510979; called by muse, mutect2
- GP6 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs575231122, COSV100117568; called by muse, mutect2
- GPR85 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 346/418 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148433444; called by muse, mutect2, varscan2
- GPRIN2 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100966407; called by muse, mutect2
- GPT2 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100412953; called by muse, mutect2, varscan2
- GRID2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV99941558; called by muse, mutect2, varscan2
- H1-2 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 140/475 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs150843466, COSV100642299; called by muse, mutect2, varscan2
- HAS2 | c.685T>G p.L229V | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100391853; called by muse, mutect2, varscan2
- HAUS8 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99505323; called by muse, mutect2, varscan2
- HEATR1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV63980919; called by muse, mutect2
- HECTD1 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 173/611 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV101237405; called by muse, mutect2, varscan2
- HGF | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV55951641; called by muse, mutect2, varscan2
- HS6ST3 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100940754; called by muse, mutect2, varscan2
- HS6ST3 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 41/459 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV100940757, COSV65017666; called by muse, mutect2
- IBSP | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99883590; called by muse, mutect2
- IFNAR2 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.095); catalogued as COSV100577109; called by muse, mutect2, varscan2
- IFNGR1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as rs868340562, COSV100880494; called by muse, mutect2
- IFT74 | c.726+1G>C p.X242_splice | Splice Site (SNP) | VAF 87/125 reads (70%) | catalogued as COSV101195799; called by muse, mutect2, varscan2
- IGKV1D-43 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 203/1002 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs768836501; called by muse, mutect2, varscan2
- IL12RB1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 493/732 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59098943; called by muse, mutect2, varscan2
- IL17RB | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 149/204 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99861201; called by muse, mutect2, varscan2
- INKA2 | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100615813; called by muse, mutect2, varscan2
- INTS7 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 135/802 reads (17%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.476); catalogued as COSV100877505; called by muse, mutect2, varscan2
- INVS | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV52441942, COSV99317618; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1642C>A p.H548N (on ENST00000485419 / NM_001197113.1; = p.H472N on NM_014575.3) | Missense Mutation (SNP) | VAF 135/186 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100541109; called by muse, mutect2, varscan2
- ITGB4 | c.2990C>A p.P997H | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs939093780, CM156565, COSV99564123; called by muse, mutect2
- ITPR1 | c.6217G>A p.D2073N (on ENST00000354582; = p.D2018N on NM_002222.7) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100231546; called by muse, mutect2, varscan2
- ITPR3 | c.6712C>G p.L2238V | Missense Mutation (SNP) | VAF 110/430 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.403); catalogued as COSV100967438; called by muse, mutect2, varscan2
- KCNA2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV60369837; called by muse, mutect2, varscan2
- KCNH7 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100036160; called by muse, mutect2, varscan2
- KDM1A | c.866C>G p.S289* | Nonsense Mutation (SNP) | VAF 69/358 reads (19%) | catalogued as COSV100752619, COSV63089497; called by muse, mutect2, varscan2
- KEAP1 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 86/116 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV50665869, COSV99407857; called by muse, mutect2, varscan2
- KIAA1549 | c.5675C>A p.S1892* (on ENST00000422774 / NM_001164665.2; = p.S1876* on NM_020910.3) | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99650931; called by muse, mutect2
- KIAA1549 | c.3829C>T p.Q1277* | Nonsense Mutation (SNP) | VAF 50/474 reads (11%) | catalogued as COSV99650934, COSV99651957; called by muse, mutect2, varscan2
- KIAA1549 | c.3279C>A p.I1093= | Splice Region (SNP) | VAF 15/130 reads (12%) | catalogued as COSV99650937; called by muse, mutect2, varscan2
- KIAA1549 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.445); catalogued as rs1328165085, COSV99650944; called by muse, mutect2, varscan2
- KIAA1549L | c.3511C>A p.P1171T (on ENST00000321505; = p.P1468T on NM_012194.3) | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773405, COSV55776193; called by muse, mutect2, varscan2
- KIDINS220 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 151/866 reads (17%) | catalogued as rs774050541, COSV56755895; called by muse, mutect2, varscan2
- KLHDC10 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 143/164 reads (87%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV100110943; called by muse, mutect2, varscan2
- KLHL21 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.494); catalogued as rs147251785, COSV100887215; called by muse, mutect2, varscan2
- KLHL7 | c.867G>C p.K289N (on ENST00000339077 / NM_001031710.3; = p.K241N on NM_018846.5) | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100178113; called by muse, mutect2, varscan2
- KRT3 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 227/290 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV100527108, COSV58816182, COSV58817076; called by muse, mutect2, varscan2
- KRTAP13-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 79/457 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1568838310; called by muse, mutect2, varscan2
- LCE1C | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 63/772 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100908446; called by muse, mutect2
- LCK | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.805); catalogued as rs763148386, COSV100287732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCMT2 | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as COSV99980082; called by muse, mutect2, varscan2
- LGSN | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 54/193 reads (28%) | catalogued as COSV101040545; called by muse, mutect2, varscan2
- LHFPL6 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 179/685 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs781528840, COSV101095370; called by muse, mutect2, varscan2
- LHX2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 118/394 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV101010056; called by muse, varscan2
- LHX2 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101010057, COSV65319099; called by muse, varscan2
- LILRB4 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV99553844; called by muse, mutect2
- LRFN2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 127/241 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599612; called by muse, mutect2, varscan2
- LRP1B | c.10987G>A p.D3663N | Missense Mutation (SNP) | VAF 99/812 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67196519; called by muse, mutect2, varscan2
- LRP2 | c.7096C>A p.P2366T | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.272); catalogued as rs1244419789, COSV55583386; called by muse, mutect2, varscan2
- LRRC3 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as rs1456283328, COSV99381773; called by muse, mutect2, varscan2
- LTN1 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100798020; called by muse, mutect2, varscan2
- MAP11 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100385510; called by muse, mutect2, varscan2
- MAP1B | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as COSV99702458; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.992); catalogued as rs1194869207, COSV99167720; called by muse, mutect2, varscan2
- MAS1L | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs560318783, COSV101009690; called by muse, mutect2, varscan2
- MAST4 | c.7774G>A p.D2592N (on ENST00000403625 / NM_001164664.2; = p.D2403N on NM_015183.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV99844425; called by muse, mutect2, varscan2
- MBLAC2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV100353144; called by muse, varscan2
- MCMDC2 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100551984; called by muse, mutect2
- MFAP2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100977626; called by muse, mutect2, varscan2
- MFAP3 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100491643, COSV59456918; called by muse, mutect2, varscan2
- MIER2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99316439; called by muse, mutect2, varscan2
- MIIP | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as rs1281227455, COSV99337615; called by muse, mutect2, varscan2
- MOSPD2 | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100996817; called by muse, mutect2, varscan2
- MPHOSPH8 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100825131; called by muse, mutect2
- MROH2B | c.4337C>G p.P1446R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV101270707; called by muse, mutect2, varscan2
- MROH2B | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.346); catalogued as COSV101270709, COSV68187770; called by muse, mutect2
- MSH4 | c.1722A>T p.L574F | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99591782; called by muse, mutect2, varscan2
- MTMR4 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100051086; called by muse, mutect2, varscan2
- MTO1 | c.1456G>A p.E486K (on ENST00000370300 / NM_133645.3; = p.E461K on NM_012123.4) | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100940443; called by muse, mutect2, varscan2
- MTTP | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99645239; called by muse, mutect2, varscan2
- MUC16 | c.36730G>C p.E12244Q | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.759); catalogued as COSV101200069, COSV67465014; called by muse, mutect2, varscan2
- MUC16 | c.29155C>T p.R9719C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.496); catalogued as rs892250234, COSV67463717; called by muse, mutect2, varscan2
- MUC5AC | c.15804A>T p.Q5268H | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV100611472; called by muse, mutect2, varscan2
- MYH15 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 61/366 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56314504; called by muse, mutect2, varscan2
- MYH15 | c.3349C>T p.Q1117* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | catalogued as COSV56312462; called by muse, mutect2, varscan2
- MYO3A | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs560394732, COSV99779972; called by muse, mutect2, varscan2
- NBEAL1 | c.4465G>A p.E1489K | Missense Mutation (SNP) | VAF 87/381 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as COSV101495707, COSV101495804; called by muse, mutect2, varscan2
- NCAPD2 | c.3022A>C p.K1008Q | Missense Mutation (SNP) | VAF 73/1611 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1441390548, COSV100217220; called by muse, mutect2
- NEK10 | c.3403G>C p.E1135Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99835249; called by muse, mutect2, varscan2
- NELFE | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100952772; called by muse, mutect2, varscan2
- NETO1 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 222/408 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100198870; called by muse, mutect2, varscan2
- NEURL4 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100224323; called by muse, mutect2, varscan2
- NIN | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 27/156 reads (17%) | catalogued as COSV55384665; called by muse, mutect2, varscan2
- NLRP14 | c.2974G>A p.G992R | Missense Mutation (SNP) | VAF 181/241 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs760582180, COSV100204407; called by muse, mutect2, varscan2
- NLRP9 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs777065030, COSV100243111; called by muse, mutect2, varscan2
- NOL4 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV99306868; called by muse, mutect2, varscan2
- NOLC1 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 246/670 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100893677; called by muse, mutect2, varscan2
- NOP53 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99884376; called by muse, mutect2, varscan2
- NUP205 | c.5722C>G p.L1908V | Missense Mutation (SNP) | VAF 154/614 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99607072; called by muse, mutect2, varscan2
- OASL | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99984547; called by muse, mutect2, varscan2
- OCIAD1 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | catalogued as COSV99971172; called by muse, mutect2, varscan2
- OLFM3 | c.1423G>A p.E475K (on ENST00000338858 / NM_001288821.1; = p.E455K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as COSV100129616; called by muse, mutect2, varscan2
- OR2L2 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 130/1105 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63551749; called by muse, mutect2, varscan2
- OR5B12 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 103/139 reads (74%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.232); catalogued as rs149439770; called by muse, mutect2, varscan2
- OR6C74 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 256/334 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as COSV100667742; called by muse, mutect2, varscan2
- OR6K3 | c.944C>A p.A315E (on ENST00000368146; = p.A299E on NM_001005327.2) | Missense Mutation (SNP) | VAF 69/1001 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs751998675, COSV100933861, COSV63745572; called by muse, mutect2
- PAIP1 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 31/322 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100166619; called by muse, mutect2
- PALB2 | c.3509A>T p.H1170L | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV99848586; called by muse, mutect2, varscan2
- PCARE | c.2168G>C p.R723T | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.32); catalogued as COSV59054468; called by muse, mutect2
- PCARE | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1239707940, COSV100527590; called by muse, mutect2
- PCDH10 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 155/215 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs777214935, COSV99993713; called by muse, mutect2, varscan2
- PCDH11X | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100012145; called by muse, mutect2, varscan2
- PCDHAC2 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV99145914; called by muse, mutect2
- PCDHGA4 | c.2224C>G p.L742V | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99539441; called by muse, mutect2, varscan2
- PCDHGA7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs763555331, COSV53903729, COSV53920818; called by muse, mutect2, varscan2
- PEX1 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 100/822 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99952151; called by muse, mutect2, varscan2
- PHF6 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100136563; called by muse, mutect2, varscan2
- PHKG1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV51917787; called by muse, mutect2, varscan2
- PHLDB2 | c.2689G>A p.D897N (on ENST00000393925 / NM_001134439.2; = p.D854N on NM_145753.2) | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV101208548; called by muse, mutect2
- PIK3CB | c.2413A>T p.K805* | Nonsense Mutation (SNP) | VAF 48/546 reads (9%) | catalogued as COSV100005718; called by muse, mutect2
- PIK3CG | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100782929; called by muse, mutect2, varscan2
- PITPNM2 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 187/231 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99759070; called by muse, mutect2, varscan2
- PITPNM3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99338478; called by muse, mutect2, varscan2
- PKHD1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 164/652 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV100583315; called by muse, mutect2, varscan2
- PKNOX2 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 128/224 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100020949; called by muse, mutect2, varscan2
- PKP2 | c.2107T>G p.L703V | Missense Mutation (SNP) | VAF 149/416 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV99297853; called by muse, mutect2, varscan2
- PLA2G4A | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 49/555 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100820567; called by muse, mutect2
- PLA2G4A | c.2121G>A p.V707= | Splice Region (SNP) | VAF 31/471 reads (7%) | catalogued as COSV100820568; called by muse, mutect2
- PLCB3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV99657464; called by muse, mutect2
- PLCE1 | c.4925A>C p.D1642A | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99595227; called by muse, mutect2, varscan2
- PLCH1 | c.2422C>G p.R808G (on ENST00000340059 / NM_001130960.2; = p.R820G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/367 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397051, COSV58193867; called by muse, mutect2, varscan2
- PLEKHH3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53188869, COSV99512044; called by muse, mutect2, varscan2
- PLEKHM3 | c.2235G>C p.E745D | Missense Mutation (SNP) | VAF 130/527 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101444309; called by muse, mutect2, varscan2
- PLPPR3 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100608758; called by muse, mutect2, varscan2
- POGLUT2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 46/524 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV99958795; called by muse, mutect2
- POLQ | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 33/424 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.037); catalogued as COSV99952347; called by muse, mutect2
- POU2F3 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99501183; called by muse, mutect2, varscan2
- POU3F1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs761836020, COSV100884702; called by muse, mutect2
- PPIA | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 100/484 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as COSV100587828; called by muse, mutect2, varscan2
- PPP1R35 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV99440096; called by muse, mutect2
- PPP2R5A | c.989T>C p.L330S | Missense Mutation (SNP) | VAF 116/139 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54818585, COSV99806700; called by muse, mutect2, varscan2
- PPP4R3B | c.1606+1G>C p.X536_splice (on ENST00000616407 / NM_001122964.3; = p.X504_splice on NM_020463.4) | Splice Site (SNP) | VAF 49/79 reads (62%) | catalogued as COSV99702101; called by muse, mutect2, varscan2
- PRDM16 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99577007; called by muse, mutect2, varscan2
- PRKDC | c.9883G>C p.E3295Q | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100040906; called by muse, mutect2, varscan2
- PRMT3 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1457696999, COSV100423950; called by muse, mutect2, varscan2
- PRPF18 | c.579+2T>A p.X193_splice | Splice Site (SNP) | VAF 75/141 reads (53%) | catalogued as COSV100187124; called by muse, mutect2, varscan2
- PRR11 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV99231570; called by muse, mutect2, varscan2
- PRRC2C | c.848G>A p.R283K (on ENST00000367742; = p.R281K on NM_015172.4) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100145360; called by muse, mutect2, varscan2
- PRUNE2 | c.3757C>A p.P1253T | Missense Mutation (SNP) | VAF 108/133 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100944503; called by muse, mutect2, varscan2
- PRX | c.2552C>G p.S851C | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99397751; called by muse, mutect2, varscan2
- PTCH2 | c.2395G>C p.D799H | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100942126; called by muse, mutect2, varscan2
- PTGDS | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs913571533, COSV56401496, COSV99811887; called by muse, mutect2, varscan2
- PTPN3 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99355853; called by muse, varscan2
- PTPRF | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 160/317 reads (50%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV100740953; called by muse, mutect2, varscan2
- PTPRF | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 130/240 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780147204, COSV63443031, COSV63447137; called by muse, mutect2
- RADIL | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 404/601 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV101271449; called by muse, mutect2, varscan2
- RAPGEF3 | c.1231C>T p.H411Y (on ENST00000389212; = p.H369Y on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.779); catalogued as COSV50197846; called by muse, mutect2, varscan2
- RAPGEF6 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 6/182 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99726657; called by muse, mutect2
- RBM15 | c.404C>A p.S135* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV63923866; called by muse, mutect2, varscan2
- RFC3 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101197825; called by muse, mutect2
- RFPL4B | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV71437705; called by muse, mutect2, varscan2
- RGL1 | c.840C>G p.I280M (on ENST00000360851 / NM_001297672.2; = p.I315M on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100486951; called by muse, mutect2
- RNF168 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 288/847 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV100534986; called by muse, mutect2, varscan2
- RNF19A | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100347746; called by muse, mutect2, varscan2
- ROR1 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV100935281; called by muse, mutect2, varscan2
- RPA3 | c.68A>T p.K23M | Missense Mutation (SNP) | VAF 171/815 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99778677; called by muse, mutect2, varscan2
- RRN3 | c.141A>T p.R47S | Missense Mutation (SNP) | VAF 194/400 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.09); catalogued as COSV99548859; called by muse, mutect2, varscan2
- S100A3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 112/669 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761565452, COSV100573022, COSV99056353; called by muse, mutect2, varscan2
- SACS | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1288922636, COSV101207485; called by muse, mutect2, varscan2
- SCAI | c.804G>A p.M268I (on ENST00000336505 / NM_001144877.3; = p.M291I on NM_173690.5) | Missense Mutation (SNP) | VAF 98/468 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.785); catalogued as COSV100332675; called by muse, mutect2, varscan2
- SCN2A | c.2847C>A p.D949E | Missense Mutation (SNP) | VAF 154/672 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99331962; called by muse, mutect2, varscan2
- SCTR | c.404G>C p.R135P | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV50034004, COSV99191604, COSV99191686; called by mutect2, varscan2
- SCYL3 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 44/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370963865; called by muse, mutect2
- SDK1 | c.5046C>G p.I1682M | Missense Mutation (SNP) | VAF 80/846 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV101269434, COSV67368990, COSV67382449; called by muse, mutect2
- SDSL | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs758497819, COSV100615256; called by muse, mutect2, varscan2
- SEC24A | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV101295030; called by muse, mutect2, varscan2
- SELENBP1 | c.1167G>A p.M389I | Missense Mutation (SNP) | VAF 104/141 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100923653; called by muse, mutect2, varscan2
- SEMA5B | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV52110850; called by muse, mutect2, varscan2
- SEPTIN12 | c.420C>A p.Y140* | Nonsense Mutation (SNP) | VAF 58/448 reads (13%) | catalogued as rs1171053168, COSV99190727; called by muse, mutect2, varscan2
- SERPINI1 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55508625, COSV99855122; called by muse, mutect2, varscan2
- SETD5 | c.3742C>G p.R1248G | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100200712; called by muse, mutect2, varscan2
- SEZ6L2 | c.2173G>T p.V725F (on ENST00000308713 / NM_001114099.3; = p.V655F on NM_012410.4) | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100435497; called by muse, mutect2, varscan2
- SFSWAP | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs890392889, COSV99906142; called by muse, mutect2, varscan2
- SH3GLB1 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100990786; called by muse, mutect2, varscan2
- SLC18B1 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 392/1412 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1185282580, COSV99259128; called by muse, mutect2, varscan2
- SLC19A2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 28/589 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99356983; called by muse, mutect2
- SLC35F1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV64510659; called by muse, varscan2
- SLC35F3 | c.422G>C p.G141A (on ENST00000366617 / NM_001300845.1; = p.G210A on NM_173508.4) | Missense Mutation (SNP) | VAF 264/354 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100784792; called by muse, mutect2, varscan2
- SLC4A7 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99839854; called by muse, mutect2, varscan2
- SLC5A1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 96/514 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833469; called by muse, mutect2, varscan2
- SLU7 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV51787686, COSV99775662; called by muse, mutect2, varscan2
- SMAD7 | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV100052816, COSV100052922; called by muse, mutect2, varscan2
- SMG8 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 101/647 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs775132577, COSV99958859; called by muse, mutect2, varscan2
- SNED1 | c.2990C>A p.A997D | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV100122768; called by muse, mutect2, varscan2
- SNTG1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 178/294 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52455523; called by muse, mutect2, varscan2
- SORCS3 | c.1951G>T p.V651F | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV63795113; called by muse, mutect2, varscan2
- SPATA31D1 | c.4240G>T p.E1414* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100782807; called by muse, mutect2, varscan2
- SPATA6 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373084426; called by muse, mutect2
- SPG11 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 134/233 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99968786; called by muse, mutect2, varscan2
- SPOCK1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV56450224; called by muse, mutect2, varscan2
- SPOCK3 | c.599-2A>T p.X200_splice | Splice Site (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100693101; called by muse, mutect2, varscan2
- SRP68 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1407704953, COSV57161359; called by muse, mutect2, varscan2
- STAG1 | c.3667G>C p.D1223H | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99365702; called by muse, mutect2, varscan2
- STEAP2 | c.987G>C p.E329D | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.593); catalogued as COSV99840460; called by muse, mutect2
- STX6 | c.679C>G p.H227D | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99275761; called by muse, mutect2
- SULF1 | c.1638G>T p.L546F | Missense Mutation (SNP) | VAF 177/282 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99483200, COSV99483313; called by muse, mutect2, varscan2
- SUSD4 | c.771C>A p.H257Q | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663571; called by muse, mutect2
- SYNJ2 | c.3421A>T p.T1141S | Missense Mutation (SNP) | VAF 226/433 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100840256; called by muse, mutect2, varscan2
- SZT2 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as COSV100161757; called by muse, mutect2, varscan2
- TAPBPL | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 20/529 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99869349; called by muse, mutect2
- TBK1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100538185; called by muse, varscan2
- TBK1 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100538186; called by muse, varscan2
- TBX15 | c.664A>T p.T222S (on ENST00000369429 / NM_001330677.2; = p.T116S on NM_152380.3) | Missense Mutation (SNP) | VAF 74/433 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99254253; called by muse, mutect2, varscan2
- TBX22 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 99/119 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs369779825, COSV100960818; called by muse, mutect2, varscan2
- TCHH | c.5374G>C p.E1792Q | Missense Mutation (SNP) | VAF 48/796 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV64277647; called by muse, mutect2
- TCHH | c.4609G>T p.E1537* | Nonsense Mutation (SNP) | VAF 58/700 reads (8%) | catalogued as COSV100915155; called by muse, mutect2
- TCHH | c.3736G>C p.E1246Q | Missense Mutation (SNP) | VAF 48/635 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.578); catalogued as rs1557809739, COSV64272813; called by muse, mutect2
- TEX13A | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 149/175 reads (85%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as rs782696967, COSV100781379; called by muse, mutect2, varscan2
- TEX14 | c.3095G>C p.R1032T (on ENST00000240361 / NM_001201457.2; = p.R1026T on NM_031272.5) | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV99542435; called by muse, mutect2, varscan2
- TFB2M | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV100830461; called by muse, mutect2
- TFG | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 30/301 reads (10%) | catalogued as COSV53749908; called by muse, mutect2
- TICRR | c.4753G>C p.E1585Q | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99176567; called by muse, mutect2, varscan2
- TJP2 | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99601212; called by muse, mutect2, varscan2
- TLE1 | c.2143A>G p.S715G | Missense Mutation (SNP) | VAF 137/185 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100918905; called by muse, mutect2, varscan2
- TMEM200A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1281919864, COSV99759376; called by muse, mutect2, varscan2
- TMEM62 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs758036233, COSV99543665; called by muse, mutect2, varscan2
- TNIK | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 34/475 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99457588; called by muse, mutect2
- TOPORS | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100745182; called by muse, mutect2, varscan2
- TPP2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as rs538453932, COSV65751030; called by muse, mutect2, varscan2
- TPR | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV100823976; called by muse, mutect2
- TPR | c.4514C>G p.S1505C | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV100823977; called by muse, mutect2, varscan2
- TRAF5 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 100/1112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99807432; called by muse, mutect2
- TRIOBP | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.06); catalogued as COSV100730888; called by muse, mutect2
- TRMT5 | c.1444+1G>A p.X482_splice | Splice Site (SNP) | VAF 162/333 reads (49%) | catalogued as COSV99712163; called by muse, mutect2, varscan2
- TRPM6 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs370195494; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54651630, COSV99535144; called by muse, mutect2, varscan2
- TTI1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 86/721 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201294118, COSV100989645; called by muse, mutect2, varscan2
- TTN | c.98296C>A p.P32766T (on ENST00000591111; = p.P25342T on NM_003319.4) | Missense Mutation (SNP) | VAF 89/295 reads (30%) | PolyPhen benign (0.009); catalogued as COSV100615958, COSV60429013; called by muse, mutect2, varscan2
- TTN | c.22498A>G p.I7500V (on ENST00000591111; = p.I6573V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/288 reads (59%) | PolyPhen benign (0); catalogued as COSV100615960; called by muse, mutect2, varscan2
- TTN | c.14724G>T p.L4908F (on ENST00000591111; = p.L3981F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 306/572 reads (53%) | PolyPhen probably damaging (0.999); catalogued as COSV100615962; called by muse, mutect2, varscan2
- UBR3 | c.4981C>A p.Q1661K | Missense Mutation (SNP) | VAF 159/702 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.9); catalogued as COSV55847018, COSV99774209; called by muse, mutect2, varscan2
- UBR4 | c.11394G>T p.Q3798H | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100920962; called by muse, mutect2, varscan2
- UGT1A8 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 124/460 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV100990654; called by muse, mutect2, varscan2
- UPK3B | c.700C>G p.L234V (on ENST00000257632; = p.L205= on NM_001347684.2) | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.019); catalogued as rs374739283, COSV99991091; called by muse, mutect2, varscan2
- URB2 | c.2855T>A p.L952* | Nonsense Mutation (SNP) | VAF 1062/1353 reads (78%) | catalogued as COSV99271273; called by muse, mutect2, varscan2
- USH2A | c.12021C>A p.D4007E | Missense Mutation (SNP) | VAF 77/926 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100236002, COSV56390348; called by muse, mutect2
- UTRN | c.8A>T p.K3M | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100839963, COSV62332091; called by muse, mutect2, varscan2
- UTRN | c.5196G>T p.E1732D | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100839964; called by muse, mutect2, varscan2
- VNN1 | c.740C>G p.A247G | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100907740; called by muse, mutect2, varscan2
- VNN3 | c.*2A>G | Splice Region (SNP) | VAF 157/623 reads (25%) | catalogued as COSV99258359; called by muse, mutect2, varscan2
- VPS13B | c.3197A>G p.H1066R | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100662205; called by muse, mutect2, varscan2
- WASHC2C | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs782409930, COSV100314038; called by muse, mutect2, varscan2
- WDR17 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99707718; called by muse, mutect2, varscan2
- WIPF2 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV100063632; called by muse, mutect2, varscan2
- WNT3A | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52733903; called by muse, mutect2, varscan2
- XRCC4 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as rs754768936, COSV99982788; called by muse, mutect2, varscan2
- XRN1 | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV99378146; called by muse, mutect2
- ZBED9 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV101509265; called by muse, mutect2, varscan2
- ZFHX4 | c.2054G>T p.R685M | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379952811, COSV99263414; called by muse, mutect2, varscan2
- ZFP64 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99402562, COSV99403109; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100362926; called by muse, mutect2, varscan2
- ZNF335 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100533057; called by muse, mutect2, varscan2
- ZNF521 | c.3878A>G p.Q1293R | Missense Mutation (SNP) | VAF 100/187 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV100832402; called by muse, mutect2, varscan2
- ZNF670 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.067); catalogued as COSV100829268; called by muse, mutect2
- ZNF708 | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 29/332 reads (9%) | catalogued as COSV100803116, COSV63609015; called by muse, mutect2
- ZNF8 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs745776060, COSV99544360; called by muse, mutect2, varscan2
- ZSWIM1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV99666584; called by muse, mutect2, varscan2
- ZSWIM5 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99870220; called by muse, mutect2, varscan2
- GPR158 | c.3366del p.A1124Lfs*2 | Frame Shift Del (DEL) | VAF 20/185 reads (11%) | called by mutect2, pindel, varscan2
- GRXCR1 | c.790dup p.C264Lfs*16 | Frame Shift Ins (INS) | VAF 123/528 reads (23%) | called by mutect2, pindel, varscan2
- KIF5C | c.868del p.D290Tfs*29 | Frame Shift Del (DEL) | VAF 30/173 reads (17%) | called by mutect2, pindel, varscan2
- KRTAP27-1 | c.602del p.G201Vfs*11 | Frame Shift Del (DEL) | VAF 42/235 reads (18%) | called by mutect2, pindel, varscan2
- MARK1 | c.915_917del p.I305del | In Frame Del (DEL) | VAF 198/244 reads (81%) | called by pindel, varscan2
- PCDHB9 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 192/490 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRDM13 | c.143dup p.V49Gfs*65 | Frame Shift Ins (INS) | VAF 59/261 reads (23%) | called by mutect2, pindel, varscan2
- RIMS1 | c.2330del p.P777Lfs*6 | Frame Shift Del (DEL) | VAF 43/93 reads (46%) | called by mutect2, pindel, varscan2
- TP53 | c.390_391del p.N131Qfs*17 | Frame Shift Del (DEL) | VAF 98/138 reads (71%) | called by mutect2, pindel, varscan2
- TRGV5 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 117/354 reads (33%) | called by muse, mutect2, varscan2
- ABCC1 | c.1593C>T p.I531= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as COSV100579710; called by muse, mutect2, varscan2
- ABRA | c.450C>T p.I150= | Silent (SNP) | VAF 59/534 reads (11%) | catalogued as rs773709951, COSV100357595; called by muse, mutect2, varscan2
- ACTN2 | c.1722C>T p.S574= | Silent (SNP) | VAF 29/372 reads (8%) | catalogued as rs753399531, COSV100856842; called by muse, mutect2
- ADAMTSL1 | c.309C>G p.G103= | Silent (SNP) | VAF 279/364 reads (77%) | catalogued as COSV99443184; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1104C>A p.I368= | Silent (SNP) | VAF 139/180 reads (77%) | catalogued as COSV99443188; called by muse, mutect2, varscan2
- AFAP1L1 | c.2223G>A p.L741= | Silent (SNP) | VAF 90/454 reads (20%) | catalogued as COSV99695921; called by muse, mutect2, varscan2
- AK3 | c.459G>A p.L153= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV100729368, COSV100729481; called by muse, mutect2, varscan2
- AKAP14 | c.558C>T p.F186= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV57631310; called by muse, mutect2, varscan2
- ANKRD30A | c.984T>A p.A328= (on ENST00000611781; = p.A272= on NM_052997.2) | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as COSV100653638; called by muse, mutect2, varscan2
- ANKRD6 | c.258G>A p.G86= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100329993; called by muse, mutect2, varscan2
- ARAP3 | c.3402C>T p.V1134= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV99499783; called by muse, mutect2, varscan2
- ARHGEF10L | c.2385C>T p.L795= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs1356909246, COSV99393002; called by muse, mutect2, varscan2
- ASCC3 | c.5580G>A p.V1860= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV64979063; called by muse, varscan2
- ASF1B | c.579C>T p.L193= | Silent (SNP) | VAF 42/503 reads (8%) | catalogued as COSV54616743; called by muse, mutect2
- ASMTL | c.363G>A p.V121= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV101187783; called by muse, mutect2, varscan2
- ATP13A5 | c.1068C>G p.V356= | Silent (SNP) | VAF 58/862 reads (7%) | catalogued as COSV100665219; called by muse, mutect2
- ATP1A3 | c.1758C>T p.L586= (on ENST00000545399 / NM_001256214.2; = p.L573= on NM_152296.5) | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100132294; called by muse, mutect2, varscan2
- BARD1 | c.2333G>A p.*778= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs776958611, COSV99638825; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCAP31 | c.321C>T p.G107= | Silent (SNP) | VAF 165/193 reads (85%) | catalogued as COSV100798943; called by muse, mutect2, varscan2
- BIRC2 | c.516G>A p.S172= | Silent (SNP) | VAF 88/475 reads (19%) | catalogued as rs1403041742, COSV99926723; called by muse, mutect2, varscan2
- BRCA2 | c.2988C>G p.L996= | Silent (SNP) | VAF 42/322 reads (13%) | catalogued as rs758336001, COSV101204281; ClinVar: likely benign; called by muse, mutect2, varscan2
- BSDC1 | c.834G>A p.E278= | Silent (SNP) | VAF 79/451 reads (18%) | catalogued as COSV61981350; called by muse, mutect2, varscan2
- C5orf15 | c.258C>A p.T86= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV99198327; called by muse, mutect2, varscan2
- CAD | c.1350C>G p.V450= | Silent (SNP) | VAF 220/1090 reads (20%) | catalogued as COSV99255147; called by muse, mutect2, varscan2
- CARD11 | c.1968G>C p.V656= | Silent (SNP) | VAF 293/467 reads (63%) | catalogued as rs756969867, COSV100829197, COSV100829356, COSV62755725; called by muse, mutect2, varscan2
- CCAR2 | c.79C>T p.L27= | Silent (SNP) | VAF 155/811 reads (19%) | catalogued as COSV99254615; called by muse, mutect2, varscan2
- CCDC181 | c.192G>A p.R64= | Silent (SNP) | VAF 33/301 reads (11%) | catalogued as COSV100890333; called by muse, mutect2, varscan2
- CD163L1 | c.3669G>T p.L1223= | Silent (SNP) | VAF 744/1040 reads (72%) | catalogued as COSV100550146; called by muse, mutect2, varscan2
- CD247 | c.120C>T p.F40= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as rs866931270, COSV100758386; called by muse, mutect2, varscan2
- CDCP2 | c.678C>T p.L226= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs748807336, COSV100313506; called by muse, mutect2, varscan2
- CDH10 | c.1671T>C p.H557= | Silent (SNP) | VAF 86/161 reads (53%) | catalogued as COSV100051730; called by muse, mutect2, varscan2
- CDS2 | c.558C>T p.V186= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as COSV100986128; called by muse, mutect2, varscan2
- CENPE | c.4329G>A p.E1443= | Silent (SNP) | VAF 48/252 reads (19%) | catalogued as COSV99478113; called by muse, mutect2, varscan2
- CEP164 | c.2991C>G p.L997= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs765549940, COSV99633523; called by muse, mutect2, varscan2
- CHD5 | c.2892C>G p.L964= | Silent (SNP) | VAF 74/435 reads (17%) | catalogued as COSV99313794; called by muse, mutect2, varscan2
- CHSY3 | c.1125G>T p.R375= | Silent (SNP) | VAF 48/210 reads (23%) | catalogued as COSV100519253; called by muse, mutect2, varscan2
- CLN3 | c.351G>A p.L117= (on ENST00000360019 / NM_001286104.2; = p.L141= on NM_000086.2) | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as COSV100343410; called by muse, mutect2, varscan2
- CNDP2 | c.1266G>A p.L422= | Silent (SNP) | VAF 83/377 reads (22%) | catalogued as COSV100159136; called by muse, mutect2, varscan2
- CNTN5 | c.1482C>A p.T494= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV99677639; called by muse, mutect2, varscan2
- COG2 | c.1992G>A p.L664= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as COSV100794696, COSV64187245; called by muse, mutect2, varscan2
- COL1A2 | c.2313C>T p.P771= | Silent (SNP) | VAF 73/381 reads (19%) | catalogued as rs144837722, COSV51964190, COSV51967573; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL25A1 | c.717A>G p.L239= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV101211463; called by muse, mutect2, varscan2
- COPE | c.363C>G p.L121= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV53232374, COSV99447581; called by muse, mutect2, varscan2
- CPB1 | c.336A>C p.T112= | Silent (SNP) | VAF 95/667 reads (14%) | catalogued as COSV99294348; called by muse, mutect2, varscan2
- CPT1A | c.2286C>T p.I762= | Silent (SNP) | VAF 192/408 reads (47%) | catalogued as rs1273692653, COSV99681234; called by muse, mutect2, varscan2
- CTTNBP2 | c.2571C>T p.D857= | Silent (SNP) | VAF 151/301 reads (50%) | catalogued as COSV99354124; called by muse, mutect2, varscan2
- CYP19A1 | c.699C>T p.I233= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99547755; called by muse, mutect2, varscan2
- CYP4F3 | c.222C>G p.L74= | Silent (SNP) | VAF 82/970 reads (8%) | catalogued as COSV55407883; called by muse, mutect2
- CYRIA | c.261G>A p.V87= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV100838422, COSV62863865; called by muse, mutect2
- DAPK1 | c.2784G>A p.L928= | Silent (SNP) | VAF 49/341 reads (14%) | catalogued as rs529643379, COSV100801996; called by muse, mutect2, varscan2
- DDX39A | c.111C>T p.S37= | Silent (SNP) | VAF 72/537 reads (13%) | catalogued as COSV99660331; called by muse, mutect2, varscan2
- DDX5 | c.57T>G p.P19= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as COSV99858021; called by muse, mutect2, varscan2
- DEPTOR | c.39C>T p.D13= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV99638682; called by muse, mutect2, varscan2
- DIO1 | c.168C>T p.F56= | Silent (SNP) | VAF 137/379 reads (36%) | catalogued as rs746714497, COSV50776500; called by muse, mutect2, varscan2
- DISP1 | c.2994G>A p.V998= | Silent (SNP) | VAF 46/586 reads (8%) | catalogued as COSV99451216; called by muse, mutect2
- DND1 | c.903C>T p.F301= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs777631380, COSV100298054; called by muse, mutect2, varscan2
- DTX4 | c.1011C>A p.I337= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV99915502; called by muse, mutect2, varscan2
- ECE1 | c.378C>T p.F126= | Silent (SNP) | VAF 64/282 reads (23%) | catalogued as COSV99941926; called by muse, mutect2, varscan2
- EFHD2 | c.357C>G p.L119= | Silent (SNP) | VAF 55/254 reads (22%) | catalogued as COSV65658018; called by muse, mutect2, varscan2
- EGFLAM | c.2571G>A p.V857= (on ENST00000354891 / NM_001205301.2; = p.V849= on NM_152403.4) | Silent (SNP) | VAF 73/656 reads (11%) | catalogued as rs1349283909, COSV100380341; called by muse, mutect2, varscan2
- ELN | c.594G>A p.P198= | Silent (SNP) | VAF 59/190 reads (31%) | catalogued as rs140337204; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- EPHX3 | c.954C>T p.I318= | Silent (SNP) | VAF 73/635 reads (11%) | catalogued as rs149458586; called by muse, mutect2, varscan2
- ERN1 | c.489C>T p.I163= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101458459; called by muse, mutect2
- F8 | c.6699G>A p.G2233= | Silent (SNP) | VAF 352/601 reads (59%) | catalogued as CD961986, COSV100371692; called by muse, mutect2, varscan2
- FAM117B | c.1554C>T p.L518= | Silent (SNP) | VAF 165/540 reads (31%) | catalogued as COSV100287532; called by muse, mutect2, varscan2
- FAT3 | c.13269C>T p.L4423= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV53123201; called by muse, mutect2, varscan2
- FAT3 | c.13587C>T p.A4529= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV99966784; called by muse, mutect2, varscan2
- FCGRT | c.90C>A p.L30= | Silent (SNP) | VAF 247/675 reads (37%) | catalogued as COSV99675307; called by muse, mutect2, varscan2
- GBP2 | c.1377G>A p.L459= | Silent (SNP) | VAF 43/250 reads (17%) | catalogued as COSV100975399; called by muse, mutect2, varscan2
- GFI1 | c.1146C>T p.N382= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV99647545; called by muse, mutect2, varscan2
- GOLGA5 | c.78C>T p.L26= | Silent (SNP) | VAF 67/193 reads (35%) | catalogued as COSV99370970; called by muse, mutect2, varscan2
- GRAMD1C | c.252G>C p.L84= | Silent (SNP) | VAF 39/546 reads (7%) | catalogued as COSV100822915; called by muse, mutect2
- GTF3C2 | c.1317C>G p.L439= | Silent (SNP) | VAF 58/762 reads (8%) | catalogued as rs749081005, COSV53125556, COSV53126931; called by muse, mutect2
- HCN4 | c.2886A>C p.P962= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV99983809; called by muse, mutect2, varscan2
- HEATR9 | c.1233G>A p.L411= | Silent (SNP) | VAF 81/376 reads (22%) | called by muse, mutect2, varscan2
- HMCN1 | c.8010T>C p.N2670= | Silent (SNP) | VAF 38/562 reads (7%) | catalogued as COSV99630048; called by muse, mutect2
- HOXA2 | c.1053C>G p.P351= | Silent (SNP) | VAF 135/566 reads (24%) | catalogued as rs570261739, COSV56065020, COSV99761248; called by muse, mutect2, varscan2
- HSPA12A | c.1377C>T p.I459= | Silent (SNP) | VAF 42/392 reads (11%) | catalogued as COSV100979836; called by muse, mutect2
- HTR7 | c.252C>T p.I84= | Silent (SNP) | VAF 62/193 reads (32%) | catalogued as rs554640114, COSV99519680; called by muse, mutect2, varscan2
- IFT122 | c.465C>T p.I155= | Silent (SNP) | VAF 66/912 reads (7%) | catalogued as COSV99959399; called by muse, mutect2
- IGLV3-21 | c.198C>G p.V66= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs372954308; called by muse, mutect2, varscan2
- IL1RL2 | c.519C>T p.F173= | Silent (SNP) | VAF 88/195 reads (45%) | catalogued as COSV99960728; called by muse, mutect2, varscan2
- INTS13 | c.882G>A p.L294= | Silent (SNP) | VAF 18/483 reads (4%) | catalogued as rs1283954445, COSV99677398; called by muse, mutect2
- IQGAP2 | c.4275G>C p.L1425= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV57183093; called by muse, mutect2, varscan2
- ITGAX | c.837A>G p.A279= | Silent (SNP) | VAF 99/308 reads (32%) | catalogued as COSV99191749; called by muse, mutect2, varscan2
- KCNA6 | c.1299G>A p.V433= | Silent (SNP) | VAF 36/821 reads (4%) | catalogued as rs776927383, COSV99768680; called by muse, mutect2
- KIAA1549 | c.4821C>G p.V1607= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99650933; called by muse, mutect2, varscan2
- KIF13B | c.5343C>G p.L1781= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101342270; called by muse, mutect2
- KIF16B | c.99G>C p.T33= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as COSV100734403; called by muse, mutect2
- KIF2C | c.1569G>A p.L523= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs1328929017, COSV100945734; called by muse, mutect2, varscan2
- KMT2E | c.3018G>A p.R1006= | Silent (SNP) | VAF 48/382 reads (13%) | catalogued as COSV99996417; called by muse, mutect2, varscan2
- LAMA3 | c.1710C>T p.L570= | Silent (SNP) | VAF 104/389 reads (27%) | catalogued as rs1486624730, COSV100556970; called by muse, mutect2, varscan2
- LAMB1 | c.4353C>G p.V1451= | Silent (SNP) | VAF 71/618 reads (11%) | catalogued as COSV99740929; called by muse, mutect2, varscan2
- LARGE1 | c.1083A>G p.S361= | Silent (SNP) | VAF 150/271 reads (55%) | catalogued as COSV61659128; called by muse, mutect2, varscan2
- LPAR4 | c.723G>A p.G241= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as COSV101425131; called by muse, mutect2, varscan2
- LRAT | c.492C>T p.F164= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs915089130, COSV60476975, COSV60477987; called by muse, mutect2, varscan2
- MAP4K5 | c.2127G>A p.L709= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99184697; called by muse, mutect2, varscan2
- MCM8 | c.1374A>C p.L458= | Silent (SNP) | VAF 216/373 reads (58%) | catalogued as COSV99495732; called by muse, mutect2, varscan2
- MPIG6B | c.264C>T p.D88= | Silent (SNP) | VAF 62/494 reads (13%) | catalogued as COSV101008110; called by muse, mutect2, varscan2
- MTOR | c.6474G>A p.P2158= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs201488400, COSV100816259; called by muse, mutect2, varscan2
- MUC17 | c.3744A>T p.T1248= | Silent (SNP) | VAF 535/5953 reads (9%) | catalogued as COSV60299519; called by muse, mutect2
- MX1 | c.861G>A p.Q287= | Silent (SNP) | VAF 68/429 reads (16%) | catalogued as COSV99912675; called by muse, mutect2, varscan2
- MYH2 | c.4276C>A p.R1426= | Silent (SNP) | VAF 199/313 reads (64%) | catalogued as rs773071482, COSV55446399, COSV99820269; called by muse, mutect2, varscan2
- MYL1 | c.225C>T p.V75= | Silent (SNP) | VAF 36/284 reads (13%) | catalogued as rs774952508, COSV58973922; called by muse, varscan2
- MYO3A | c.2073C>G p.V691= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV99779970; called by muse, mutect2, varscan2
- NAGLU | c.882C>T p.L294= | Silent (SNP) | VAF 170/571 reads (30%) | catalogued as rs753128312, COSV99864173; called by muse, mutect2, varscan2
- NOM1 | c.1929A>G p.L643= | Silent (SNP) | VAF 113/131 reads (86%) | catalogued as COSV99315788; called by muse, mutect2, varscan2
- NPAS3 | c.795C>T p.I265= (on ENST00000356141 / NM_001164749.2; = p.I233= on NM_022123.3) | Silent (SNP) | VAF 120/319 reads (38%) | catalogued as COSV100640260, COSV60868728; called by muse, mutect2, varscan2
- NQO2 | c.27C>T p.V9= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as COSV100583212; called by muse, mutect2, varscan2
- NYNRIN | c.111C>G p.V37= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV101230607; called by muse, mutect2, varscan2
- OBSCN | c.18669C>T p.T6223= | Silent (SNP) | VAF 24/280 reads (9%) | catalogued as COSV99479320; called by muse, mutect2
- OR11A1 | c.759T>C p.Y253= | Silent (SNP) | VAF 95/335 reads (28%) | catalogued as COSV101010710; called by muse, mutect2, varscan2
- OR14K1 | c.51G>A p.E17= | Silent (SNP) | VAF 38/462 reads (8%) | catalogued as COSV51720365, COSV99315242; called by muse, mutect2
- OR6C76 | c.147G>T p.L49= | Silent (SNP) | VAF 157/390 reads (40%) | catalogued as COSV100094109; called by muse, mutect2, varscan2
- OR8H2 | c.54G>A p.L18= | Silent (SNP) | VAF 130/611 reads (21%) | catalogued as COSV100542353; called by muse, mutect2, varscan2
- ORC1 | c.1047A>T p.P349= | Silent (SNP) | VAF 51/277 reads (18%) | catalogued as COSV100856685; called by muse, mutect2, varscan2
- OSBPL6 | c.2619A>G p.Q873= | Silent (SNP) | VAF 111/531 reads (21%) | catalogued as COSV99507628; called by muse, mutect2, varscan2
- PAPOLA | c.978G>T p.T326= | Silent (SNP) | VAF 108/206 reads (52%) | catalogued as COSV99354291; called by muse, mutect2, varscan2
- PCDHB11 | c.2157G>T p.A719= | Silent (SNP) | VAF 264/687 reads (38%) | catalogued as COSV61314045, COSV61314188; called by muse, mutect2
- PCDHGA11 | c.2085G>C p.V695= | Silent (SNP) | VAF 73/254 reads (29%) | catalogued as COSV99539443; called by muse, mutect2, varscan2
- PKD2 | c.693C>G p.L231= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99417430; called by muse, mutect2, varscan2
- PLD4 | c.450C>T p.N150= | Silent (SNP) | VAF 55/184 reads (30%) | catalogued as rs754683873, COSV66915166; called by muse, mutect2, varscan2
- PLEKHG4B | c.27C>G p.P9= (on ENST00000283426; = p.P365= on NM_052909.5) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99360401; called by muse, mutect2, varscan2
- POLQ | c.4296G>A p.K1432= | Silent (SNP) | VAF 165/360 reads (46%) | catalogued as rs148117258; called by muse, mutect2, varscan2
- PRDM9 | c.153T>C p.Y51= | Silent (SNP) | VAF 225/565 reads (40%) | catalogued as COSV57007814, COSV99690548; called by muse, mutect2, varscan2
- PYROXD2 | c.1047G>C p.L349= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV100995998; called by muse, mutect2, varscan2
- RASD2 | c.525G>A p.K175= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV99332813; called by muse, mutect2, varscan2
- RBM14 | c.711C>T p.Y237= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as rs1187667422, COSV59559603; called by muse, mutect2, varscan2
- RHAG | c.441A>G p.L147= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV100006635; called by muse, mutect2, varscan2
- RPL11 | c.63C>G p.L21= (on ENST00000374550 / NM_001199802.1; = p.L22= on NM_000975.5) | Silent (SNP) | VAF 177/499 reads (35%) | catalogued as COSV65778863; called by muse, mutect2, varscan2
- RPS6KA1 | c.1152C>T p.T384= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as rs745989127, COSV65175977; called by muse, mutect2, varscan2
- SALL3 | c.2934G>C p.V978= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV101610010; called by muse, mutect2, varscan2
- SDCCAG8 | c.535C>T p.L179= | Silent (SNP) | VAF 66/489 reads (13%) | catalogued as COSV100654221, COSV100654314; called by muse, mutect2, varscan2
- SEMA6A | c.1821G>A p.K607= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV99145780; called by muse, mutect2, varscan2
- SENP8 | c.390G>A p.K130= | Silent (SNP) | VAF 50/237 reads (21%) | catalogued as COSV100566547; called by muse, mutect2, varscan2
- SLC12A7 | c.2958G>A p.L986= | Silent (SNP) | VAF 187/791 reads (24%) | catalogued as COSV99370003; called by muse, mutect2, varscan2
- SLC13A2 | c.1290C>A p.A430= | Silent (SNP) | VAF 93/360 reads (26%) | catalogued as rs1555604263, COSV100120340; called by muse, mutect2, varscan2
- SLC16A2 | c.345C>T p.F115= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs961941086, COSV99330750; called by muse, mutect2, varscan2
- SLC22A25 | c.1437G>T p.G479= | Silent (SNP) | VAF 331/445 reads (74%) | catalogued as COSV100123645; called by muse, mutect2, varscan2
- SLC25A22 | c.381G>A p.L127= | Silent (SNP) | VAF 52/67 reads (78%) | catalogued as COSV57192878; called by muse, mutect2, varscan2
- SLC34A2 | c.1269G>T p.G423= | Silent (SNP) | VAF 50/291 reads (17%) | catalogued as COSV101158364; called by muse, mutect2, varscan2
- SLC4A4 | c.2082C>T p.L694= (on ENST00000264485 / NM_001098484.3; = p.L650= on NM_003759.4) | Silent (SNP) | VAF 10/229 reads (4%) | catalogued as COSV99140355; called by muse, mutect2
- SLC52A2 | c.1218G>A p.L406= | Silent (SNP) | VAF 77/418 reads (18%) | catalogued as COSV100095792; called by muse, mutect2, varscan2
- SP8 | c.30C>T p.G10= (on ENST00000361443 / NM_198956.4; = p.G28= on NM_182700.6) | Silent (SNP) | VAF 60/264 reads (23%) | catalogued as COSV100815366; called by muse, mutect2, varscan2
- SPATA31D1 | c.228C>T p.F76= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV100782806; called by muse, mutect2, varscan2
- SPHKAP | c.2394T>C p.G798= | Silent (SNP) | VAF 303/557 reads (54%) | catalogued as COSV100764154; called by muse, mutect2, varscan2
- SRP14 | c.28C>T p.L10= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1317262413, COSV99139546; called by muse, mutect2, varscan2
- SRRM4 | c.918C>A p.G306= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as COSV99938643; called by muse, mutect2, varscan2
- SUPT6H | c.654T>C p.G218= | Silent (SNP) | VAF 152/288 reads (53%) | catalogued as rs372505724; called by muse, mutect2, varscan2
- SYNE1 | c.3066G>A p.L1022= (on ENST00000367255 / NM_182961.4; = p.L1029= on NM_033071.3) | Silent (SNP) | VAF 103/322 reads (32%) | catalogued as COSV99566590; called by muse, mutect2, varscan2
- SYNJ1 | c.573G>A p.Q191= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100449354; called by muse, mutect2, varscan2
- TAAR6 | c.651T>C p.Y217= | Silent (SNP) | VAF 66/235 reads (28%) | catalogued as COSV99256746; called by muse, mutect2, varscan2
- TAF3 | c.2724C>T p.F908= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100720186; called by muse, mutect2, varscan2
- TECRL | c.513A>G p.G171= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV101168993; called by muse, mutect2, varscan2
- TELO2 | c.1827C>T p.R609= | Silent (SNP) | VAF 44/408 reads (11%) | catalogued as rs760147994, COSV99248425; called by muse, mutect2, varscan2
- THNSL2 | c.1386G>A p.L462= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100147504; called by muse, mutect2
- TMCO1 | c.719G>A p.*240= (on ENST00000612311 / NM_001256164.1; = p.*189= on NM_019026.6) | Silent (SNP) | VAF 50/534 reads (9%) | catalogued as COSV100903164; called by muse, mutect2
- TMEM135 | c.1314C>T p.F438= | Silent (SNP) | VAF 90/249 reads (36%) | catalogued as COSV100449766; called by muse, mutect2, varscan2
- TMEM39A | c.1440C>A p.L480= | Silent (SNP) | VAF 22/330 reads (7%) | catalogued as COSV100052430, COSV59901159; called by muse, mutect2
- TNN | c.2595G>T p.V865= | Silent (SNP) | VAF 36/406 reads (9%) | catalogued as rs771716198, COSV99512116; called by muse, mutect2
- TNS3 | c.3729G>A p.P1243= | Silent (SNP) | VAF 108/310 reads (35%) | catalogued as rs779317865, COSV100235551; called by muse, mutect2, varscan2
- TOR1AIP1 | c.189G>A p.P63= | Silent (SNP) | VAF 303/354 reads (86%) | catalogued as COSV99621370; called by muse, mutect2, varscan2
- TRAP1 | c.1449C>T p.L483= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1326734984, COSV99893541; called by muse, mutect2, varscan2
- TRRAP | c.4893C>T p.T1631= (on ENST00000359863 / NM_001244580.1; = p.T1613= on NM_003496.3) | Silent (SNP) | VAF 70/323 reads (22%) | catalogued as rs1419103267, COSV100722557; called by muse, mutect2, varscan2
- TSC22D4 | c.342G>T p.G114= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV100278903; called by muse, mutect2
- TTC7A | c.1131G>A p.Q377= | Silent (SNP) | VAF 25/256 reads (10%) | catalogued as COSV99766498; called by muse, mutect2, varscan2
- UBA2 | c.1461A>C p.G487= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99875556; called by muse, mutect2, varscan2
- UBAP2L | c.1863C>T p.F621= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as COSV55181985; called by muse, mutect2
- XPO6 | c.1245C>T p.F415= | Silent (SNP) | VAF 93/468 reads (20%) | catalogued as COSV100485070; called by muse, mutect2, varscan2
- ZIC1 | c.234C>A p.G78= | Silent (SNP) | VAF 35/219 reads (16%) | catalogued as COSV99292002; called by muse, varscan2
- ZIC1 | c.282C>T p.F94= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as COSV99292006; called by muse, varscan2
- ZMAT1 | c.321G>A p.E107= | Silent (SNP) | VAF 86/102 reads (84%) | catalogued as COSV100858829, COSV65659773; called by muse, mutect2, varscan2
- ZNF208 | c.2664C>A p.P888= | Silent (SNP) | VAF 177/311 reads (57%) | catalogued as COSV101237043; called by muse, mutect2, varscan2
- ZNF785 | c.648C>G p.L216= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as rs370549514; called by muse, mutect2, varscan2
- ADAD2 | c.419-363C>G | Intron (SNP) | VAF 28/171 reads (16%) | catalogued as COSV99235355; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500354 ins T | 5'Flank (INS) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- CCDC144B | n.178G>A | RNA (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- CCT6A | c.1213+79C>T | Intron (SNP) | VAF 22/204 reads (11%) | catalogued as COSV99303496; called by muse, mutect2, varscan2
- CPLANE1 | c.*4627G>A | 3'UTR (SNP) | VAF 57/224 reads (25%) | catalogued as COSV99950741; called by muse, mutect2, varscan2
- DEPDC5 | c.*687G>T | 3'UTR (SNP) | VAF 29/51 reads (57%) | catalogued as COSV99835570; called by muse, mutect2, varscan2
- FAM43B | c.-1G>C | 5'UTR (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100261611; called by muse, mutect2, varscan2
- FLCN | c.871+82C>T | Intron (SNP) | VAF 13/285 reads (5%) | catalogued as rs1037586456, COSV99550450; called by muse, mutect2
- H2BP2 | chr1:143876204 A>C | 3'Flank (SNP) | VAF 98/128 reads (77%) | called by mutect2, varscan2
- KRAS | c.*96C>G | 3'UTR (SNP) | VAF 14/273 reads (5%) | catalogued as COSV99780268; called by muse, mutect2
- MIR412 | n.83C>G | RNA (SNP) | VAF 58/311 reads (19%) | called by muse, mutect2, varscan2
- NOP56 | c.1010+141G>C | Intron (SNP) | VAF 54/173 reads (31%) | catalogued as COSV100250141; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3732G>A | Intron (SNP) | VAF 28/568 reads (5%) | catalogued as COSV99387287; called by muse, mutect2
- RPL10A | c.-2C>T | 5'UTR (SNP) | VAF 38/194 reads (20%) | catalogued as rs371703850; called by muse, mutect2, varscan2
- TTN | c.10360+2051T>G | Intron (SNP) | VAF 45/466 reads (10%) | catalogued as COSV100615965; called by muse, mutect2
- ZNFX1 | chr20:49280334 G>A | 5'Flank (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
